Gene-level copy-number profile of tumor specimen ALCH-B2VN-TTP1-A from ALCHEMIST case ALCH-B2VN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 79.1 years (28,909 days).
Specimen ALCH-B2VN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4ebd0884-d080-407e-925b-3b5a3d86811f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2VN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/384e85b7-f63d-4822-8995-cf5eb762da30

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 14,231; copy number 2: 35,515; copy number 3: 5,633; copy number 4: 2,333; copy number 5: 96; copy number 6: 58; copy number 7: 36; copy number 8: 22; copy number 9: 98; copy number 10: 122; copy number 11: 37; copy number 12: 1; copy number 13: 41; copy number 14: 7; copy number 15: 1; copy number 16: 1; copy number 17: 30; copy number 18: 2; copy number 19: 8; copy number 21: 1; copy number 22: 4; copy number 23: 14; copy number 24: 35; copy number 32: 1; copy number 41: 29.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,352,689–1,361,777, 1 gene: MXRA8.
- chr2:241,849,884–241,858,894, 1 gene: PDCD1.
- chr4:3,463,306–3,532,446, 2 genes: DOK7, LRPAP1.
- chr8:12,104,389–12,115,516, 1 gene: ZNF705D.
- chr8:46,784,800–46,907,309, 9 genes: AC021451.1, TRIM60P15, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3.
- chr9:39,191,100–39,191,360, 1 gene (within-gene range 0–1): RN7SL640P.
- chr12:131,894,622–131,923,150, 2 genes: ULK1, AC131009.4.
- chr21:7,744,962–8,454,792, 26 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 644 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–4,013,649, 90 genes, copy number 6–19 (broad region; genes not listed).
- chr5:8,143,618–8,157,788, 2 genes, copy number 8: AC091912.2, AC091912.1.
- chr5:12,297,399–12,804,363, 5 genes, copy number 5–9: RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1.
- chr5:13,553,654–14,871,778, 16 genes, copy number 8: NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637.
- chr5:21,341,833–22,853,344, 6 genes, copy number 5–21 (within-gene range 3–23): GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12.
- chr5:22,139,247–22,213,761, 3 genes, copy number 11: AC139497.1, PMCHL1, AC138854.1.
- chr5:22,754,227–22,766,824, 1 gene, copy number 11: AC091938.1.
- chr5:23,443,586–26,013,025, 33 genes, copy number 7–9: PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, CDH10, AC091885.2, AC091885.1, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, RNU4-43P.
- chr5:34,656,328–35,048,135, 10 genes, copy number 5: RAI14, AC025754.1, AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21, AGXT2.
- chr5:35,617,844–35,814,611, 1 gene, copy number 24 (within-gene range 4–24): SPEF2.
- chr5:35,678,484–38,468,339, 54 genes, copy number 6–41: AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P, GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1.
- chr5:41,585,882–42,924,535, 22 genes, copy number 5–15 (within-gene range 3–15): AC008817.1, OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6, AC108099.1, GHR, SERBP1P6, AC093225.1, AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5.
- chr7:32,456,963–33,062,797, 22 genes, copy number 5: AC018641.1, SLC25A5P5, LSM5, AVL9, DPY19L1P1, ZNRF2P1, MIR550A2, MIR550B2, AC018645.3, LINC00997, AC018645.1, AC018645.2, DPY19L1P2, AC018648.1, KBTBD2, RP9P, AC083863.1, FKBP9, RNU6-388P, NT5C3A, RPS29P14, RN7SL505P.
- chr7:62,275,361–62,275,678, 1 gene, copy number 5: AC128676.1.
- chr8:66,667,596–66,860,472, 1 gene, copy number 5 (within-gene range 4–5): C8orf44-SGK3.
- chr8:66,712,734–66,926,398, 5 genes, copy number 5: SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87.
- chr9:39,734,670–39,741,193, 2 genes, copy number 9: RAB28P1, RBPJP5.
- chr11:11,656,651–11,811,530, 5 genes, copy number 13: MIR4299, AC131935.2, AC131935.1, AC104383.1, MIR8070.
- chr11:12,030,875–12,540,967, 9 genes, copy number 12–22: LINC02547, AC124276.1, AC124276.2, MICAL2, MIR6124, AC079329.1, AC025300.1, PARVA, AC009806.1.
- chr11:61,055,392–61,639,449, 29 genes, copy number 10: AP003721.2, CD5, VPS37C, AP000437.1, PGA3, PGA4, AP003037.1, PGA5, VWCE, DDB1, TKFC, CYB561A3, AP003108.3, TMEM138, TMEM216, CPSF7, AP003108.4, AP003108.2, SDHAF2, RN7SL23P, PPP1R32, AP003108.1, MIR4488, LRRC10B, SYT7, AP003108.5, AP003559.1, AP002754.1, RPLP0P2.
- chr11:69,371,463–69,819,416, 12 genes, copy number 13–18: AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3.
- chr12:61,600,067–61,600,843, 1 gene, copy number 9: DUX4L52.
- chr12:62,965,325–70,637,440, 176 genes, copy number 6–24 (broad region; genes not listed).
- chr12:71,125,085–72,186,618, 17 genes, copy number 7–9 (within-gene range 1–9): TSPAN8, LGR5, AC090116.1, AC078860.3, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1.
- chr12:73,820,315–74,728,851, 12 genes, copy number 9: LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1, AC123904.2, AC123904.1, AC123904.3.
- chr12:76,115,711–77,317,234, 20 genes, copy number 5 (within-gene range 5–13): AC233290.2, AC233290.1, RNU6-1271P, LNCOG, RN7SKP172, BBS10, OSBPL8, AC107032.2, AC107032.3, RPL7AP9, YWHAQP7, AC107032.1, RPL7P43, AC093014.1, ZDHHC17, CSRP2, AC124784.1, AC025161.1, E2F7, LINC02464.
- chr13:26,905,362–28,138,193, 37 genes, copy number 10: FGFR1OP2P1, AL160035.1, RPS21P8, RPS20P32, USP12, AL158062.1, USP12-AS1, USP12-AS2, LINC02340, LINC00412, RPL21, SNORD102, SNORA27, RASL11A, RNU6-70P, LINC01079, RNY1P1, GTF3A, MTIF3, RNU6-63P, LNX2, POLR1D, AL136439.1, NPM1P4, GSX1, PLUT, RNU6-73P, PDX1, ATP5F1EP2, LINC00543, CDX2, URAD, RN7SL272P, FLT3, KATNBL1P1, CHCHD2P8, PAN3-AS1.
- chr14:18,333,726–18,419,273, 4 genes, copy number 8: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:34,659,564–35,809,304, 33 genes, copy number 13–23 (within-gene range 2–23): Metazoa_SRP, RNU6-1261P, RPL23AP8, CFL2, RPL12P6, BAZ1A, RNU7-41P, AL121603.2, SRP54-AS1, AL121603.1, IGBP1P1, SRP54, FAM177A1, PPP2R3C, AL049776.1, PRORP, AL121594.1, RPL23AP70, SEPTIN7P1, MRPL57P8, DPRXP3, RPL7AP3, RPL9P3, PSMA6, AL133163.2, AL133163.1, NFKBIA, DNAJC8P1, AL133163.3, RPS3AP4, KRT18P6, INSM2, RALGAPA1.
- chr14:41,296,286–41,298,734, 1 gene, copy number 32: AL391516.1.
- chr20:48,624,252–48,849,458, 3 genes, copy number 6: PREX1, AL035106.1, AL133342.1.
- chr20:51,098,138–51,802,521, 7 genes, copy number 5: AL121785.1, RPSAP1, NFATC2, MIR3194, ATP9A, AL138807.1, SALL4.
- chr21:12,999,676–13,113,790, 4 genes, copy number 5–10: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P.

Autosomal genes at a single copy (total copy number 1): 14,222. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
